Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8DT, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8DT-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Body)

1 - "Stomach + omentum":

-Poorly differentiated adenocarcinoma (intestinal pattern of Laurén) infiltrating the serosa;

-Greatest dimension of tumor: 8.6 cm;

-Angiolymphatic invasion: present;

-Perineural invasion: not detected;

-Surgical margins: uninvolved by neoplasia.

-Omentum: absence of neoplasia.

Lymph nodes of greater curvature: involved by neoplasia (4/19).

Lymph nodes of lesser curvature: involved by neoplasia (3/27).

2 - "Chain 12A lymph nodes":

Involved by neoplasia (2/3).

3 - "Chain 8P lymph nodes":

Absence of neoplasia (0/4).

4 - "Chain 8A lymph nodes":

Fragment of pancreatic tissue uninvolved by neoplasia.

5 - "Gallbladder":

Chronic cholecystitis.

6 - "Esophageal margin":

Absence of neoplasia.

ICD-O-3

Adenocarcinoma, intestinal type
8144/3
Site Body of stomach C16.2

QW 11/28/13

Diagnosis Discrepancy	Ad 10/24/13	

Source: NCI Genomic Data Commons file 943a4506-d899-4de3-8726-a29f6ada82f4 (TCGA-VQ-A8DT.6A7C4B02-E05D-4319-B89D-A3C101E31448.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).